Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3732, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3732-01A (Primary Tumor).

Diagnosis/diagnoses:

Rectosigmoid resection material shows a moderately differentiated adenocarcinoma of the colorectal type, located immediately above the dentate line, measuring max 2.5 cm in diameter, with infiltration of the tunica muscularis propria and evidence of lymph vessel invasion. Tumor-free resection margins. Twelve tumor-free regional lymph nodes.

Stage of the tumor is: pT2, pN0 (0/12) pMX; G2, L1, V0, R0

Source: NCI Genomic Data Commons file febf7e62-4eae-4979-b611-79cba39eb7e8 (TCGA-AG-3732.34485425-8A63-4A59-89F5-F0D651D0BF18.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).